Somatic mutation profile of tumor specimen TCGA-QH-A6CX-01A (aliquot TCGA-QH-A6CX-01A-11D-A32B-08) from TCGA case TCGA-QH-A6CX, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 66.4 years (24,252 days).
Specimen TCGA-QH-A6CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 770a1e7b-cf51-418f-8e1a-17618f9ba0f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6CX-10A (Blood Derived Normal), aliquot TCGA-QH-A6CX-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0d6827c-9cbd-483c-b538-bec441086adc

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 24, Silent 12, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCR9 | c.884T>C p.I295T (on ENST00000357632 / NM_031200.3; = p.I283T on NM_006641.4) | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100591615; called by muse, mutect2, varscan2
- COL3A1 | c.3535G>A p.G1179S | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM970363, COSV100482625; called by muse, mutect2, varscan2
- DOCK2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56947055; called by muse, mutect2, varscan2
- EDAR | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757450239, COSV51500429; called by muse, mutect2
- EGFR | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 219/258 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV51785554, COSV51829933; called by muse, mutect2, varscan2
- IGF1R | c.3482A>G p.Y1161C | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769891354, COSV99149445; called by muse, mutect2, varscan2
- IKZF2 | c.1372T>G p.Y458D | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100563297; called by muse, mutect2, varscan2
- KIR3DL3 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV99400480; called by muse, mutect2, varscan2
- LHX8 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs756685357, COSV99633193, COSV99633738; called by muse, mutect2, varscan2
- MIA3 | c.5485C>A p.P1829T | Missense Mutation (SNP) | VAF 60/287 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100388084; called by muse, mutect2, varscan2
- MUC16 | c.29255C>T p.S9752F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.412); catalogued as COSV67450031; called by muse, mutect2, varscan2
- MUC17 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 80/450 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100071999, COSV99058536; called by muse, mutect2, varscan2
- NF1 | c.2867C>T p.T956I | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1323973848, COSV100646225; called by muse, mutect2, varscan2
- OR2L3 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs186782673, COSV100741928; called by muse, mutect2, varscan2
- OR5H14 | c.753C>A p.Y251* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV101454145, COSV71194292; called by muse, mutect2, varscan2
- PCDHB6 | c.378del p.N126Kfs*14 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | catalogued as COSV50689475; called by mutect2, pindel, varscan2
- PDE6A | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs761022237, COSV54928350; called by muse, mutect2, varscan2
- RBM19 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55694543; called by muse, mutect2, varscan2
- ROS1 | c.2327C>T p.T776M | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs149313880; called by muse, mutect2, varscan2
- RPS18 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV101005572; called by muse, mutect2
- RXFP1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369872878; called by muse, varscan2
- SCN5A | c.1784T>G p.V595G | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100346850; called by muse, mutect2, varscan2
- SIMC1 | c.614G>A p.R205Q (on ENST00000443967 / NM_001308196.1; = p.R224Q on NM_001308195.2) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs371703466; called by muse, mutect2
- TRIM42 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs146449412; called by muse, mutect2, varscan2
- TSPEAR | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.08); catalogued as rs782774422, COSV59959995; called by muse, mutect2, varscan2
- TTC22 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs540310870, COSV64881803; called by muse, mutect2, varscan2
- ZBED9 | c.2811G>C p.L937F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101509148; called by muse, mutect2, varscan2
- ASTL | c.1077G>A p.S359= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as rs148115152; called by muse, mutect2, varscan2
- CHAF1B | c.1245G>A p.P415= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs376013076; called by muse, mutect2, varscan2
- EDAR | c.600C>T p.I200= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs901116756, COSV99303193; called by muse, mutect2, varscan2
- GJA10 | c.951T>C p.N317= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV101005294; called by muse, mutect2, varscan2
- JHY | c.1710G>A p.Q570= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99912829; called by muse, mutect2, varscan2
- MLKL | c.987C>T p.H329= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs367604583, COSV58205163; called by muse, mutect2
- MS4A5 | c.27G>A p.P9= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs768189050; called by muse, mutect2
- SERPIND1 | c.390C>T p.N130= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs144089172, COSV53138191; called by muse, mutect2, varscan2
- SLC28A1 | c.1191G>A p.E397= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99722669; called by muse, mutect2
- STEAP1 | c.666G>A p.L222= | Silent (SNP) | VAF 34/214 reads (16%) | called by muse, mutect2, varscan2
- SYNE1 | c.6979T>C p.L2327= (on ENST00000367255 / NM_182961.4; = p.L2334= on NM_033071.3) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99555730; called by muse, mutect2, varscan2
- THEM5 | c.420G>A p.S140= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs762789735, COSV64312774; called by muse, mutect2
